FM case AD13277 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/76b6269a-d903-4f15-b928-6a2ea855a131

Female, 55.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the fallopian tube; metastasis. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
